Somatic mutation profile of tumor specimen C3L-03367-01 (aliquot CPT0239700006) from CPTAC case C3L-03367, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 71.6 years (26,149 days).
Specimen C3L-03367-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b460944a-73c7-4cc5-8a3a-748eaedf55c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03367-31 (Blood Derived Normal), aliquot CPT0240500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3df5e71-8087-4ede-b481-936b5d28d822

The open-access MAF lists 49 somatic variants for this specimen: 33 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 15, Frame Shift Ins 2, Intron 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 335/540 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs121913513, CM133722, COSV55386593, COSV55412340; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- AKNA | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 105/448 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs140395838; called by muse, mutect2, varscan2
- ANKRD1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 68/311 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.123); catalogued as COSV65467447; called by muse, mutect2, varscan2
- ARAP3 | c.4525C>T p.P1509S | Missense Mutation (SNP) | VAF 76/477 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV53353602; called by muse, mutect2, varscan2
- DNAJC21 | c.1636C>A p.L546I | Missense Mutation (SNP) | VAF 256/3357 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57762776; called by muse, mutect2
- HIVEP3 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 106/447 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs775439332; called by muse, mutect2, varscan2
- LAMA5 | c.6759+1G>A p.X2253_splice | Splice Site (SNP) | VAF 162/440 reads (37%) | catalogued as rs764287262; called by muse, mutect2, varscan2
- LOXHD1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs184934277; called by muse, mutect2
- MMP21 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 15/461 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1039538575; called by muse, mutect2
- OR2AP1 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 119/1472 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.629); catalogued as COSV58725502; called by muse, mutect2
- OR4K15 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1433864012; called by muse, mutect2, varscan2
- PDZD2 | c.3917G>A p.R1306Q | Missense Mutation (SNP) | VAF 120/3330 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs544825168, COSV56866088; called by muse, mutect2
- RAB33A | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 82/195 reads (42%) | catalogued as COSV57062233, COSV57063641; called by muse, mutect2, varscan2
- SNCAIP | c.1181A>C p.K394T | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54415408; called by muse, mutect2, varscan2
- TLL1 | c.2295T>G p.N765K | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV50280737; called by muse, mutect2, varscan2
- TSPOAP1 | c.2594G>A p.R865Q | Missense Mutation (SNP) | VAF 149/520 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs757521869, COSV52115944; called by muse, mutect2, varscan2
- AKAP9 | c.1005C>G p.N335K | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- BTNL8 | c.1167C>A p.F389L | Missense Mutation (SNP) | VAF 101/201 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CDK12 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.952); called by muse, varscan2
- EP400 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 43/1112 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by muse, mutect2
- ERBB3 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 235/677 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2
- IMPA1 | c.86dup p.N29Kfs*2 | Frame Shift Ins (INS) | VAF 53/295 reads (18%) | called by mutect2, pindel, varscan2
- JUNB | c.401dup p.F135Lfs*249 | Frame Shift Ins (INS) | VAF 124/555 reads (22%) | called by mutect2, pindel, varscan2
- KCNN3 | c.1568T>C p.I523T (on ENST00000618040 / NM_001204087.1; = p.I508T on NM_002249.6) | Missense Mutation (SNP) | VAF 106/627 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KMT5A | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 93/1208 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- NAV3 | c.4931C>T p.A1644V | Missense Mutation (SNP) | VAF 146/593 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, varscan2
- OR2AP1 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 106/1727 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); called by muse, mutect2
- PCLO | c.4502A>G p.D1501G | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS20 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TAS2R41 | c.851T>A p.I284N | Missense Mutation (SNP) | VAF 111/478 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TENT5A | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 110/527 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TERT | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 1649/2179 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- WRN | c.3865A>G p.M1289V | Missense Mutation (SNP) | VAF 18/467 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.019); called by muse, mutect2
- ADCY10 | c.1116C>T p.F372= | Silent (SNP) | VAF 19/415 reads (5%) | called by muse, mutect2
- AGTR2 | c.792C>T p.A264= | Silent (SNP) | VAF 142/274 reads (52%) | catalogued as rs192038692; called by muse, mutect2, varscan2
- ATG13 | c.684C>G p.P228= | Silent (SNP) | VAF 26/282 reads (9%) | catalogued as rs1283600865; called by muse, mutect2
- DNAH10 | c.1098C>T p.V366= (on ENST00000409039; = p.V305= on NM_207437.3) | Silent (SNP) | VAF 108/1470 reads (7%) | catalogued as COSV101292254; called by muse, mutect2
- ITPR2 | c.1209C>T p.I403= | Silent (SNP) | VAF 68/309 reads (22%) | called by muse, mutect2, varscan2
- MYL10 | c.345G>A p.A115= | Silent (SNP) | VAF 115/380 reads (30%) | catalogued as rs375406824, COSV56207128; called by muse, mutect2, varscan2
- OR51E2 | c.129C>T p.I43= | Silent (SNP) | VAF 246/446 reads (55%) | catalogued as rs574634498, COSV67807277; called by muse, mutect2, varscan2
- PBX1 | c.597G>T p.R199= | Silent (SNP) | VAF 303/492 reads (62%) | called by muse, mutect2, varscan2
- PITPNM2 | c.1269C>T p.H423= | Silent (SNP) | VAF 124/1127 reads (11%) | catalogued as rs1293374098; called by muse, mutect2, varscan2
- RETNLB | c.54C>A p.I18= | Silent (SNP) | VAF 121/361 reads (34%) | called by muse, mutect2, varscan2
- RNF215 | c.831G>A p.A277= | Silent (SNP) | VAF 93/290 reads (32%) | catalogued as rs755036120, COSV99306647; called by muse, mutect2, varscan2
- SCLY | c.999C>T p.D333= (on ENST00000651534; = p.D325= on NM_016510.7) | Silent (SNP) | VAF 94/399 reads (24%) | catalogued as rs1433969078; called by muse, mutect2, varscan2
- SORL1 | c.4449G>A p.T1483= | Silent (SNP) | VAF 204/443 reads (46%) | catalogued as rs560299380, COSV52760727; called by muse, mutect2, varscan2
- WDFY4 | c.4575C>T p.S1525= | Silent (SNP) | VAF 69/410 reads (17%) | called by muse, mutect2
- ZNF112 | c.2121C>T p.Y707= (on ENST00000337401 / NM_001083335.2; = p.Y701= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 88/437 reads (20%) | catalogued as COSV61620315; called by muse, mutect2, varscan2
- ERBB3 | c.421+83C>T | Intron (SNP) | VAF 215/630 reads (34%) | called by muse, mutect2, varscan2
